Somatic mutation profile of tumor specimen MP2PRT-PAUUIL-TBP1-A (aliquot MP2PRT-PAUUIL-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAUUIL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (692 days).
Specimen MP2PRT-PAUUIL-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a6ffca2-8d07-4705-8670-89758e171a7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUIL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUIL-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c28b65d-35f4-4de7-9e4d-b7002e5adf30

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 44/386 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MCF2L | c.3337G>A p.V1113I (on ENST00000375608; = p.V1081I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/663 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.131); catalogued as rs767900174; called by muse, mutect2, varscan2
- MYH10 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52603199; called by muse, mutect2
- OR51E2 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755299731, COSV67807363; called by muse, mutect2
- PRICKLE2 | c.410C>T p.P137L (on ENST00000295902; = p.P81L on NM_198859.4) | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99897617; called by muse, mutect2
- SERPINA2 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 61/495 reads (12%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as rs748167425; called by muse, mutect2, varscan2
- TEX13D | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs1389500901; called by muse, mutect2
- KDM4C | c.2341G>C p.A781P | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHGB4 | c.908A>C p.N303T | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- UBE2N | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, varscan2
- PRKACA | c.699C>T p.A233= | Silent (SNP) | VAF 43/285 reads (15%) | catalogued as rs996572658, COSV100431797, COSV58070574; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4644_170-4643insT | Intron (INS) | VAF 49/363 reads (13%) | called by mutect2, pindel*, varscan2
